Somatic mutation profile of tumor specimen MMRF_2827_1_BM_CD138pos (aliquot MMRF_2827_1_BM_CD138pos_T1_KHS5U_L16549) from MMRF case MMRF_2827, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2827_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7f02e71-4400-4a5f-b1d3-abc246355e32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2827_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2827_1_PB_WBC_C2_KHS5U_L16596; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d1488fa-ac18-4fb8-8d1e-c3ca5bc169af

The open-access MAF lists 134 somatic variants for this specimen: 53 protein-altering or splice-affecting, 20 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 34, Silent 20, Intron 13, 5'UTR 9, 3'Flank 3, Nonsense Mutation 3, Frame Shift Del 3, RNA 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB1 | c.1991C>T p.A664V (on ENST00000360697 / NM_001346687.2; = p.A624V on NM_001112.4) | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs138974538; called by muse, mutect2, varscan2
- C1orf162 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 12/369 reads (3%) | catalogued as COSV100636197; called by muse, mutect2
- COG5 | c.1049A>G p.Y350C | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1388958454, COSV51749143; called by muse, mutect2, varscan2
- EIF2B1 | c.223T>C p.F75L | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57459047; called by muse, mutect2
- FBN1 | c.4444G>T p.G1482C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57318057, COSV57326581; called by muse, mutect2, varscan2
- FCGBP | c.6788C>T p.P2263L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as rs1216338714; called by muse, mutect2, varscan2
- GATA6 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1194509310, COSV99036222; called by muse, mutect2, varscan2
- GPX7 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs765974878; called by muse, mutect2, varscan2
- IGHV2-70 | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 68/114 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368641348; called by muse, varscan2
- IGHV2-70 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs72690597; called by muse, varscan2
- IGLV3-1 | c.118A>C p.T40P | Missense Mutation (SNP) | VAF 120/196 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs189772470; called by muse, varscan2
- KLF17 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100955001, COSV64856586; called by muse, mutect2
- LURAP1L | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748947927, COSV59983885; called by muse, mutect2, varscan2
- MBTPS1 | c.846+1G>A p.X282_splice | Splice Site (SNP) | VAF 37/100 reads (37%) | catalogued as rs760091079; called by muse, mutect2, varscan2
- MTMR1 | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 104/107 reads (97%) | catalogued as COSV64892793; called by muse, mutect2, varscan2
- NOX4 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1247382424; called by muse, varscan2
- OR10Q1 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.463); catalogued as rs376884240, COSV57472141; called by muse, mutect2
- PRDM4 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.453); catalogued as COSV57307711; called by muse, mutect2
- SPHKAP | c.3326C>T p.P1109L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs756170282, COSV100764119, COSV60879220; called by muse, mutect2, varscan2
- TKTL2 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs776821649, COSV54917974; called by muse, mutect2, varscan2
- ZFPM2 | c.2204C>G p.T735R | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV101023076, COSV101023148; called by muse, mutect2, varscan2
- ZSCAN9 | c.1083_1084del p.E363Afs*7 | Frame Shift Del (DEL) | VAF 35/148 reads (24%) | catalogued as rs764249012; called by mutect2, pindel, varscan2
- ADGRL3 | c.1426T>C p.Y476H (on ENST00000506720 / NM_001322402.2; = p.Y408H on NM_015236.6) | Missense Mutation (SNP) | VAF 101/198 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ANAPC15 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 105/395 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CASP4 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 117/464 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CLEC16A | c.4T>G p.F2V | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CNTN3 | c.2819T>C p.V940A | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DCAF4L2 | c.92A>C p.K31T | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- GLCE | c.312T>A p.Y104* | Nonsense Mutation (SNP) | VAF 21/370 reads (6%) | called by muse, mutect2
- H2BC17 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- HIF1A | c.2327C>G p.S776C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- IGHD3-3 | c.3del p.L2Yfs*? | Frame Shift Del (DEL) | VAF 10/12 reads (83%) | called by mutect2, varscan2
- KANK1 | c.896G>C p.R299T | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LSM14A | c.73A>T p.I25F | Missense Mutation (SNP) | VAF 237/392 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MC1R | c.545A>T p.Y182F | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- MICOS13 | c.38T>G p.I13S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MTNR1B | c.469A>C p.T157P | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NFATC4 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP12 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- NUP205 | c.1162T>A p.Y388N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PANK2 | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHA9 | c.1022T>A p.V341E | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.108); called by muse, mutect2
- SAFB2 | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SELENOV | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- SLC18A1 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, varscan2
- SLC2A5 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SOX1 | c.428C>G p.A143G | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT tolerated (0.35); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPICE1 | c.124del p.H42Ifs*22 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- TMEFF2 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.087); called by muse, mutect2
- TTC28 | c.3586C>T p.R1196W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF17 | c.1086A>T p.E362D | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2
- ZNF770 | c.1411A>G p.R471G | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); called by mutect2, varscan2
- ZYX | c.1587C>A p.N529K | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ACTA1 | c.897C>T p.N299= | Silent (SNP) | VAF 58/130 reads (45%) | catalogued as rs533868659, COSV64203504; called by muse, mutect2, varscan2
- ADGRA2 | c.825C>T p.N275= | Silent (SNP) | VAF 38/49 reads (78%) | catalogued as rs752343931, COSV100178443; called by muse, mutect2, varscan2
- ANGPTL4 | c.870C>T p.S290= | Silent (SNP) | VAF 48/148 reads (32%) | catalogued as rs774693998, COSV56844368; called by muse, mutect2, varscan2
- ATP2B2 | c.915C>T p.D305= (on ENST00000352432; = p.D316= on NM_001001331.4) | Silent (SNP) | VAF 44/143 reads (31%) | catalogued as rs748937189, COSV59506172; called by muse, mutect2, varscan2
- CARD11 | c.465G>A p.R155= | Silent (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- COG4 | c.1839G>A p.T613= | Silent (SNP) | VAF 48/100 reads (48%) | catalogued as rs565871794; called by muse, mutect2, varscan2
- H2BC17 | c.360C>T p.T120= | Silent (SNP) | VAF 62/192 reads (32%) | called by muse, mutect2, varscan2
- HSPA2 | c.873C>T p.Y291= | Silent (SNP) | VAF 62/110 reads (56%) | catalogued as COSV55969058; called by muse, mutect2, varscan2
- IGLV3-1 | c.99A>C p.P33= | Silent (SNP) | VAF 74/205 reads (36%) | catalogued as rs373803208; called by muse, varscan2
- IKBKE | c.474C>T p.F158= | Silent (SNP) | VAF 66/126 reads (52%) | catalogued as rs781921985, COSV65624372; called by muse, mutect2, varscan2
- ITGB7 | c.381G>A p.R127= | Silent (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- LRRK1 | c.5643A>G p.L1881= | Silent (SNP) | VAF 144/335 reads (43%) | called by muse, mutect2, varscan2
- RTN1 | c.1866C>T p.S622= | Silent (SNP) | VAF 44/84 reads (52%) | catalogued as rs772270786, COSV50721100; called by muse, mutect2, varscan2
- SLC38A10 | c.891C>T p.S297= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- SUSD4 | c.1257C>T p.D419= | Silent (SNP) | VAF 56/117 reads (48%) | catalogued as rs1464158430; called by muse, mutect2, varscan2
- TLE1 | c.1749C>T p.S583= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as rs752460555; called by muse, mutect2, varscan2
- TLE2 | c.1278C>T p.D426= | Silent (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- TMEM67 | c.318T>G p.G106= | Silent (SNP) | VAF 111/273 reads (41%) | called by muse, mutect2, varscan2
- YJEFN3 | c.792C>T p.S264= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs759482321; called by muse, mutect2, varscan2
- ZNF236 | c.3651C>T p.H1217= | Silent (SNP) | VAF 39/157 reads (25%) | called by muse, mutect2, varscan2
- ADGRG6 | c.*2675A>C | 3'UTR (SNP) | VAF 18/22 reads (82%) | called by muse, mutect2, varscan2
- ASB7 | c.*1450C>G | 3'UTR (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- ASTN2 | c.*328G>T | 3'UTR (SNP) | VAF 56/218 reads (26%) | called by muse, mutect2
- ATP8B4 | c.*1334T>G | 3'UTR (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- ATP9B | c.3013-290T>C | Intron (SNP) | VAF 24/76 reads (32%) | catalogued as rs1568861561; called by muse, mutect2, varscan2
- ATPAF1 | chr1:46632833 C>T | 3'Flank (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- B4GALT4 | c.903-1343C>G | Intron (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021574 G>C | 5'Flank (SNP) | VAF 57/135 reads (42%) | catalogued as COSV104379335; called by muse, mutect2, varscan2
- BMP5 | c.*997A>C | 3'UTR (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- C5orf60 | n.1918G>T | RNA (SNP) | VAF 145/446 reads (33%) | catalogued as rs1386178895, COSV101495125; called by muse, mutect2, varscan2
- CHMP2B | c.*652G>A | 3'UTR (SNP) | VAF 4/94 reads (4%) | catalogued as COSV55461760; called by muse, mutect2
- CSTF2T | c.*1167A>C | 3'UTR (SNP) | VAF 63/125 reads (50%) | called by muse, mutect2, varscan2
- CTTNBP2NL | c.*873C>T | 3'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- CTXN2 | c.*2178C>T | 3'UTR (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
- CYB5R2 | c.*6C>A | 3'UTR (SNP) | VAF 126/363 reads (35%) | called by muse, mutect2, varscan2
- CYFIP1 | chr15:22868138 C>T | 3'Flank (SNP) | VAF 64/260 reads (25%) | called by muse, mutect2, varscan2
- DYNLRB1 | c.80-3750T>C | Intron (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- EFHB | c.-117G>A | 5'UTR (SNP) | VAF 51/163 reads (31%) | called by muse, mutect2, varscan2
- ERCC8 | c.*101A>C | 3'UTR (SNP) | VAF 118/192 reads (61%) | called by muse, mutect2, varscan2
- ETV1 | c.*215G>C | 3'UTR (SNP) | VAF 50/145 reads (34%) | called by muse, mutect2, varscan2
- FEM1B | c.*3686C>T | 3'UTR (SNP) | VAF 65/142 reads (46%) | called by muse, mutect2, varscan2
- FXYD5 | c.-77C>T | 5'UTR (SNP) | VAF 69/222 reads (31%) | called by muse, mutect2, varscan2
- GABRA3 | c.*1073C>T | 3'UTR (SNP) | VAF 30/41 reads (73%) | called by muse, mutect2, varscan2
- H2AZ2 | chr7:44828002 A>G | 3'Flank (SNP) | VAF 44/70 reads (63%) | called by muse, mutect2, varscan2
- HBE1 | c.-160G>T | 5'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- IDNK | c.51-1489T>C | Intron (SNP) | VAF 16/48 reads (33%) | catalogued as rs527291236, COSV99461657; called by muse, mutect2, varscan2
- IL18RAP | c.-100-12C>A | Intron (SNP) | VAF 68/143 reads (48%) | catalogued as rs1327945308; called by muse, mutect2, varscan2
- IRF1 | c.187+51G>C | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2
- JCAD | c.*2416dup | 3'UTR (INS) | VAF 38/111 reads (34%) | called by mutect2, pindel, varscan2
- KLHDC7B | c.*518G>A | 3'UTR (SNP) | VAF 78/184 reads (42%) | called by muse, mutect2, varscan2
- KMO | c.-43A>C | 5'UTR (SNP) | VAF 92/205 reads (45%) | called by muse, mutect2, varscan2
- LRRC49 | c.-26A>C | 5'UTR (SNP) | VAF 102/453 reads (23%) | called by muse, mutect2, varscan2
- LTO1 | c.346-795A>G | Intron (SNP) | VAF 60/178 reads (34%) | catalogued as rs767619740; called by muse, mutect2, varscan2
- MCF2 | c.*276C>A | 3'UTR (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- MDM1 | c.-15C>T | 5'UTR (SNP) | VAF 85/165 reads (52%) | catalogued as rs575599732; called by muse, mutect2, varscan2
- METTL15 | c.*2064C>T | 3'UTR (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- NLGN3 | c.*996A>T | 3'UTR (SNP) | VAF 3/14 reads (21%) | catalogued as rs1459651475; called by muse, mutect2
- NSD1 | c.927+1124C>G | Intron (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- PELO | c.-489T>G | 5'UTR (SNP) | VAF 121/196 reads (62%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*903G>A | 3'UTR (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- PKNOX2 | c.816+175A>G | Intron (SNP) | VAF 21/22 reads (95%) | catalogued as rs570367266; called by muse, varscan2
- PLCB1 | c.*2934A>C | 3'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- POLR3B | c.-63T>G | 5'UTR (SNP) | VAF 42/76 reads (55%) | called by muse, mutect2, varscan2
- PSD2 | c.*1669A>G | 3'UTR (SNP) | VAF 95/143 reads (66%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+4228C>T | Intron (SNP) | VAF 36/135 reads (27%) | catalogued as rs1458959002; called by muse, varscan2
- PYGO1 | c.*4446T>A | 3'UTR (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- RFX7 | c.*1738G>A | 3'UTR (SNP) | VAF 10/127 reads (8%) | catalogued as rs1181657670; called by muse, mutect2
- RPS6KB1 | c.*1873A>T | 3'UTR (SNP) | VAF 20/41 reads (49%) | catalogued as rs973136164; called by muse, varscan2
- SERTAD4 | c.*1315G>A | 3'UTR (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- SESN3 | c.*5164G>A | 3'UTR (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- SHANK2 | c.*2278T>G | 3'UTR (SNP) | VAF 73/124 reads (59%) | called by muse, mutect2, varscan2
- SLC13A5 | c.*358C>T | 3'UTR (SNP) | VAF 38/86 reads (44%) | catalogued as rs186891452; called by muse, mutect2, varscan2
- SLC24A1 | c.*281G>A | 3'UTR (SNP) | VAF 30/170 reads (18%) | called by muse, mutect2, varscan2
- SLC6A5 | c.*2533del | 3'UTR (DEL) | VAF 30/106 reads (28%) | catalogued as COSV54229643; called by mutect2, pindel, varscan2
- TENT2 | c.*857T>C | 3'UTR (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- TMEM144 | c.109+12T>C | Intron (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- TOLLIP | c.*835G>C | 3'UTR (SNP) | VAF 64/281 reads (23%) | called by muse, mutect2, varscan2
- TPD52 | c.*1043A>C | 3'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- TRABD | c.421-102C>T | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- ZEB1 | c.58+2087A>G | Intron (SNP) | VAF 64/132 reads (48%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.-920T>C | 5'UTR (SNP) | VAF 62/116 reads (53%) | called by muse, mutect2, varscan2
